Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A25B, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A25B-01A (Primary Tumor).

[page 1 of 4]
This report contains corrections, additions or deletions.
Any previous versions are stored internally and are available if necessary.

Specimen:

Received:

Status:

Req#:

Spec Type: SURGICAL P

Subm Dr:

PRELIMINARY DIAGNOSIS

LEFT BREAST CANCER INVASIVE

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: SENTINEL NODE RX/SIMPLE MASTECTOMY

CLINICAL HISTORY

- A. LT SENTINEL NODE #1 - FS
- B. LEFT BREAST
- C. LEFT AXILLARY NODES
- D. ADDITIONAL ANTERIOR MARGIN OF THE INFERIOR PORTION OF LEFT BREAST

PRELIMINARY DIAGNOSIS

A. METASTATIC CARCINOMA

GROSS DESCRIPTION

PART A IS RECEIVED DESIGNATED [REDACTED] SENTINEL LYMPH NODE #1. IT IS RECEIVED IN THE FRESH STATE FOR FROZEN SECTION AND CONSISTS OF A FRAGMENT OF YELLOWISH-PINK FIBROADIPOSE TISSUE WITH 2 PALPABLE NODULES, THE SPECIMEN HAVING OVERALL DIMENSIONS 4.3 X 2.7 X 1.5 CM WITH THE LARGEST NODULE MEASURING 2 X 2 X 1 CM AND THE SMALLER 1.5 X 1.2 X 0.3 CM. SECTIONING THE LARGER NODULE SHOWS MULTIPLE GRAY-WHITE NODULES WITHIN A TANNISH-PINK PARENCHYMA MEASURING UP TO 0.6 X 0.4 X 0.4 CM. THE SMALLER NODULE ON SECTIONING REVEALS A TANNISH-PURPLE PARENCHYMA WITH A 0.8 X 0.5 X 0.5-CM GRAYISH-TAN NODULE. THE SECTIONS SUBMITTED FOR FROZEN SECTION ARE SUBMITTED FOR PERMANENTS LABELED [REDACTED] SECTIONS OF UNFROZEN TISSUE ARE SUBMITTED WITH A REPRESENTATIVE SECTION FROM THE LARGEST NODULE AND THE REMAINING SMALLER NODULE ENTIRELY. REPRESENTATIVE SECTIONS ARE SUBMITTED AS FOLLOWS: FSA SECTION FROM LARGER AND SMALLER NODULES IN 1 CASSETTE: A1--CROSS SECTION OF LARGEST NODULE, A2--SMALLER NODULE ENTIRELY, SECTION.

PART B RECEIVED LABELED [REDACTED] LEFT BREAST, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 23.5 X 22 X 8.0 CM. THE NIPPLE IS UNREMARKABLE WITHIN A 13.5 X 9-CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH

ICA-0-3

carcinoma, infiltrating duct, nos 8500/3
Site: breast, NOS 250.9 per 4/27/11

[page 2 of 4]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

(Continued)

BLACK. SECTIONING REVEALS YELLOW FATTY TISSUE INTERSPERSED WITH PINK-TAN GRANULAR FIBROUS TISSUE WHICH IS PRESENT DIFFUSELY THROUGHOUT THE BREAST. IN THE 6 AND 7 O'CLOCK AREA, THERE IS A FIRM PINK-TAN LESION WHICH HAS A CENTRAL CYLINDRICAL-SHAPED METAL CLIP. THIS FIRM AREA MEASURES 4 X 2.5 X 3 CM IN GREATEST DIMENSIONS. IT GROSSLY EXTENDS TO WITHIN 0.8 CM OF THE DEEP MARGIN AND 0.3 CM OF THE SUPERFICIAL MARGIN. SUPERIOR AND CENTRAL WITHIN THE BREAST, THERE IS A 4.5 X 2-CM AREA OF FATTY TISSUE WITHOUT FIBROUS BANDS WHICH GROSSLY SEEMS DELINEATED FROM THE SURROUNDING PARENCHYMAL TISSUE (B2). SECTIONS ARE SUBMITTED AS FOLLOWS: B1--NIPPLE, B2--CENTRAL FATTY TISSUE, B3--TUMOR AND SUPERFICIAL MARGIN, B4 THROUGH B7--FULL CROSS-SECTION OF THE LESION TO INCLUDE THE DEEP AND SUPERFICIAL MARGIN, B8--FIBROUS TISSUE IMMEDIATELY LATERAL TO THE LESION, B9--TISSUE IMMEDIATELY MEDIAL TO LESION IN LOWER INNER QUADRANT, B10--UPPER INNER QUADRANT 14 CM FROM LESION, B11--TISSUE AT 9 O'CLOCK 9 CM FROM LESION, B12--LOWER OUTER QUADRANT 4 CM FROM LESION, B13--3 O'CLOCK 13 CM FROM LESION, B14--UPPER OUTER QUADRANT 15 CM FROM LESION, B15--ADDITIONAL SECTION OF TUMOR AND SUPERFICIAL MARGIN. SECTIONS OF TUMOR AND BREAST TISSUE ARE SUBMITTED PER PROTOCOL.

AFTER X-RAYING THE SPECIMEN, A CLIP IS IDENTIFIED IN THE 6 O'CLOCK AREA AT THE EDGE OF THE SKIN ELLIPSE. THIS IS 3 CM ANTERIOR AND LATERAL TO THE PREVIOUSLY DESCRIBED LESION. THIS AREA CONSISTS OF A RED-BROWN CLOT SURROUNDED BY INDURATED YELLOW-TAN FATTY TISSUE MEASURING 1.7 X 1.0 X 1.5 CM. THIS IS 0.5 CM FROM THE INFERIOR SUPERFICIAL MARGIN AND 3.5 CM FROM THE DEEP MARGIN. SECTIONS FROM THIS AREA ARE SUBMITTED IN B16 THROUGH B19. B20--DEEP MARGIN TO LESION, B21--TISSUE TAKEN BETWEEN THIS LESION AND THE LARGER TUMOR MASS. TISSUE IS ALSO TAKEN FROM THE SECOND AREA PER PROTOCOL.

PART C RECEIVED LABELED [REDACTED] LEFT AXILLARY NODE, IS YELLOW-RED FATTY TISSUE MEASURING 7.5 X 6 X 1.7 CM. THIS IS EXAMINED FOR LYMPH NODES. ALSO LOOSE WITHIN THE CONTAINER IS A 1-CM OVOID RED-TAN STRUCTURE. THIS IS CONSISTENT WITH A GROSSLY UNREMARKABLE LYMPH NODE. IT IS SECTIONED AND SUBMITTED LABELED C1 WITH A PORTION SUBMITTED PER PROTOCOL. THREE LARGER NODES ARE IMMEDIATELY IDENTIFIABLE WITHIN THE FATTY TISSUE. THESE ARE SECTIONED WITH ONE-HALF OF EACH SUBMITTED WITHIN C2 THROUGH C4, RESPECTIVELY, WITH C3 GROSSLY POSITIVE. SECTIONS OF THESE NODES ARE ALSO SUBMITTED PER PROTOCOL. ADDITIONAL NODES ARE SUBMITTED AS FOLLOWS: C5--FOUR NODES.

PART D RECEIVED LABELED [REDACTED] ADDITIONAL ANTERIOR MARGIN OF THE INFERIOR PORTION OF LEFT BREAST STITCH MARKS 12 O'CLOCK, IS AN ELLIPTICAL PORTION OF BROWN PIGMENTED SKIN MEASURING 16 X 2.7 X 0.9 CM. ALONG THE MIDPORTION OF ONE EDGE IS A SUTURE DENOTING 12 O'CLOCK. THIS EDGE IS MARKED WITH BLUE INK. THE 3 O'CLOCK SIDE OF THE SPECIMEN IS THEN MARKED BLACK AND THE 9 O'CLOCK RED. THE 3 O'CLOCK ELLIPTICAL END IS AMPUTATED AND BISECTED LONGITUDINALLY AND SUBMITTED AS

[page 3 of 4]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

(GROSS DESCRIPTION)

(Continued)

D1. THE 9 O'CLOCK ELLIPTICAL END IS AMPUTATED AND BISECTED LONGITUDINALLY AND SUBMITTED LABELED D2. BY PALPATION, THERE IS SOME NODULARITY IN THE CENTRAL PORTION OF THE SPECIMEN AND CROSS-SECTIONS ARE SUBMITTED IN D3 AND 4. ADDITIONAL SECTIONS FROM THE 3 O'CLOCK SIDE ARE SUBMITTED IN D5 AND ADDITIONAL SECTIONS FROM THE 9 O'CLOCK SIDE ARE SUBMITTED IN D6.

PATH PROVIDED

PROCEDURES:

PATH FS , A BLK/2, B BLK/15, C BLK/5, D BLK/6, FS-A

FINAL DISSECTION

PART A LEFT AXILLA, SENTINEL LYMPH NODE #1: METASTATIC BREAST CARCINOMA IS PRESENT IN ONE OF TWO LYMPH NODES EXAMINED. EXTRANODAL EXTENSION IS NOT IDENTIFIED.

1/2 SN

PART B (LEFT) BREAST, SIMPLE MASTECTOMY:

1. INTRADUCTAL AND INFILTRATING DUCT CARCINOMA. INVASIVE COMPONENT IS POORLY DIFFERENTIATED SHOWING NUCLEAR GRADE 3/3, MODERATE MITOTIC INDEX AND TUBULE FORMATION 3 WITH TOTAL NOTTINGHAM SCORE OF 8. HIGH GRADE DCIS OF THE CRIBRIFORM AND SOLID TYPES HAVING AREAS OF COMEDONECROSIS IS IDENTIFIED SURROUNDING AND WITHIN THE TUMOR WITH EXTENSION INTO TERMINAL LOBULES COMPRISING APPROXIMATELY 20% OF THE TUMOR.
2. THE INVASIVE COMPONENT HAS A MAXIMUM GROSS DIMENSION OF 4 CM AND IS FOCALLY IDENTIFIED APPROXIMATELY 2 MM FROM THE NEAREST INKED SUPERFICIAL MARGIN (B15).
3. RANDOM SECTIONS OF THE REMAINING QUADRANTS AND NIPPLE SKIN ARE FREE OF TUMOR. SEE COMMENT.
4. LYMPHOVASCULAR INVASION IS IDENTIFIED.
5. THE BIOPSY SITE IS PRESENT.
6. DIFFUSE LACTATIONAL CHANGES.

IDC 3/3/2
4cm

20% DCIS gr 3
crib
solid
comedo
lob ca

⊖ margin
⊖ skin
⊖ nipple
+ LVI

Bx Δ

lactational Δ

PART C LEFT AXILLA, LYMPH NODE DISSECTION: METASTATIC BREAST CARCINOMA IS IDENTIFIED IN 1 OF 6 LYMPH NODES EXAMINED. EXTRANODAL EXTENSION IS NOT SEEN.

1/6 AN

[page 4 of 4]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

(Continued)

PART D LEFT BREAST, ADDITIONAL ANTERIOR MARGIN OF THE INFERIOR PORTION,
EXCISION: SKIN AND SUBCUTANEOUS TISSUE WITH NO EVIDENCE OF RESIDUAL
TUMOR AND CLEAR MARGIN. (C)

COMMENT

THE SECOND BIOPSY SITE WAS NOT IDENTIFIED ON INITIAL GROSS EXAMINATION.
THE SPECIMEN WILL BE X-RAYED TO FIND THE BIOPSY CLIP AND ADDITIONAL
SECTIONS WILL BE SUBMITTED.

ADDITIONAL SECTIONS SURROUNDING THE SECOND BIOPSY SITE SHOW DCIS, SOME OF
WHICH EXTENDS INTO TERMINAL LOBULES, RARE MICROSCOPIC FOCI OF
INFILTRATING DUCT CARCINOMA, AND LYMPHOVASCULAR INVASION.

OCLS
vare IDC
FLVI
lob ca

1

signed _____ Electronically signed by: _____

Source: NCI Genomic Data Commons file c43a99e4-3b0f-4550-ab09-135d1f096f3c (TCGA-A2-A25B.FCE29F34-5D13-4A21-A950-A8577C957C10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).